Somatic mutation profile of tumor specimen C3L-01607-03 (aliquot CPT0092180009) from CPTAC case C3L-01607, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 83.4 years (30,462 days).
Specimen C3L-01607-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94f4c25c-4e8b-4538-98e2-a933ed21f1ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01607-31 (Blood Derived Normal), aliquot CPT0093750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63716826-3857-4d81-bfe2-514b03d3d298

The open-access MAF lists 111 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Intron 8, Frame Shift Del 7, 3'UTR 6, Splice Site 3, Nonsense Mutation 3, RNA 2, Splice Region 1, 5'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.880G>A p.V294M | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as rs747355273; called by muse, mutect2, varscan2
- BBX | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772688060, COSV57881501; called by muse, mutect2, varscan2
- CYP2A13 | c.773C>A p.T258K | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138089886, COSV57836209; called by muse, mutect2, varscan2
- DHRS9 | c.384G>C p.E128D | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs1439921018, COSV59139683; called by muse, mutect2, varscan2
- EIF5A | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as COSV100222692; called by muse, mutect2, varscan2
- EXOC5 | c.887G>T p.R296M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV61770803; called by muse, mutect2, varscan2
- FAM71B | c.1328G>C p.S443T | Missense Mutation (SNP) | VAF 67/307 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs767349540, COSV57231403; called by muse, mutect2, varscan2
- FOXD4 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 125/568 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV58700483; called by muse, mutect2, varscan2
- GTF2H1 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 39/170 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs551071012, COSV56377387; called by muse, mutect2, varscan2
- KLHL7 | c.224-1G>A p.X75_splice (on ENST00000339077 / NM_001031710.3; = p.X27_splice on NM_018846.5) | Splice Site (SNP) | VAF 81/377 reads (21%) | catalogued as COSV59161996; called by muse, mutect2, varscan2
- KMT2D | c.5140C>A p.P1714T | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV56494634; called by muse, mutect2, varscan2
- MAPT | c.1135C>T p.H379Y (on ENST00000262410 / NM_001377265.1; = p.H304Y on NM_016835.4) | Missense Mutation (SNP) | VAF 93/347 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1213524576, COSV99291158, COSV99291236; called by muse, mutect2, varscan2
- RCL1 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 35/501 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as rs138474156; called by muse, mutect2
- SERPINH1 | c.565A>T p.T189S | Missense Mutation (SNP) | VAF 68/225 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.418); catalogued as rs138784081; called by muse, mutect2, varscan2
- SLC3A2 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 81/317 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs931124662; called by muse, mutect2, varscan2
- SUZ12 | c.1278A>T p.L426F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as rs773744548; called by muse, mutect2, varscan2
- THSD7A | c.2466G>C p.K822N | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV70265705; called by muse, mutect2, varscan2
- TMEM25 | c.974_976del p.N325del | In Frame Del (DEL) | VAF 62/286 reads (22%) | catalogued as rs1555061837; called by pindel, varscan2
- ABCA13 | c.14218A>G p.I4740V | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- AHDC1 | c.3638C>A p.S1213Y | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AMH | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ATP2C1 | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 56/186 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BPIFB6 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- C1GALT1 | c.158A>C p.D53A | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC32 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- CD4 | c.1304T>A p.I435N | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CERS1 | c.822_823insT p.V275Cfs*3 | Frame Shift Ins (INS) | VAF 60/240 reads (25%) | called by mutect2, pindel, varscan2
- CFAP43 | c.2495A>C p.E832A | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHST9 | c.1080T>A p.C360* | Nonsense Mutation (SNP) | VAF 75/266 reads (28%) | called by muse, mutect2, varscan2
- CRP | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 127/420 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CTDSPL2 | c.973del p.Y325Mfs*2 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- CTSA | c.616A>G p.N206D | Missense Mutation (SNP) | VAF 129/491 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFB118 | c.352_364del p.N118Afs*26 | Frame Shift Del (DEL) | VAF 36/123 reads (29%) | called by mutect2, pindel, varscan2
- DLG5 | c.895C>G p.L299V | Missense Mutation (SNP) | VAF 80/283 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- EVPL | c.1624G>T p.E542* | Nonsense Mutation (SNP) | VAF 62/288 reads (22%) | called by muse, mutect2, varscan2
- FAM186B | c.466T>A p.C156S | Missense Mutation (SNP) | VAF 121/504 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- FAM227A | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GON4L | c.5996T>C p.V1999A | Missense Mutation (SNP) | VAF 82/435 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIGD1A | c.134del p.L45Yfs*4 | Frame Shift Del (DEL) | VAF 44/165 reads (27%) | called by mutect2, pindel, varscan2
- HMCN2 | c.11251G>T p.A3751S | Missense Mutation (SNP) | VAF 63/270 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HTATSF1 | c.2201_2208del p.E734Afs*12 | Frame Shift Del (DEL) | VAF 54/90 reads (60%) | called by mutect2, pindel
- HYKK | c.783del p.Y262Mfs*12 | Frame Shift Del (DEL) | VAF 70/307 reads (23%) | called by mutect2, pindel, varscan2
- KDM5C | c.3682A>T p.T1228S | Missense Mutation (SNP) | VAF 91/182 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KDM5C | c.3121-15_3133del p.X1041_splice | Splice Site (DEL) | VAF 40/164 reads (24%) | called by mutect2, pindel
- KNG1 | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 71/144 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- KRCC1 | c.440G>C p.S147T | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LIN28A | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGA | c.8713G>C p.E2905Q (on ENST00000219905 / NM_001164273.1; = p.E2696Q on NM_001080541.2) | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MINK1 | c.2011A>G p.R671G | Missense Mutation (SNP) | VAF 66/324 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- MINK1 | c.2012G>T p.R671M | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MROH9 | c.1440T>A p.D480E | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACA | c.235-1G>T p.X79_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- PARD3 | c.1147A>G p.S383G | Missense Mutation (SNP) | VAF 96/388 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARD6B | c.518T>C p.I173T | Missense Mutation (SNP) | VAF 70/241 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PBRM1 | c.3604A>C p.T1202P (on ENST00000296302 / NM_001366071.2; = p.T1177P on NM_018313.5) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA6 | c.122A>G p.H41R | Missense Mutation (SNP) | VAF 77/458 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDHB12 | c.431A>T p.E144V | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.9839T>A p.M3280K | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PSD | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.351); called by muse, mutect2
- RPL10A | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEL1L3 | c.2586-16_2586-5del | Splice Region (DEL) | VAF 38/147 reads (26%) | called by mutect2, pindel, varscan2
- SH2B1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- SKP1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 104/552 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC25A13 | c.1514C>A p.A505D | Missense Mutation (SNP) | VAF 99/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SLC25A13 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 99/527 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SMYD4 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 98/348 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- SPTAN1 | c.2967G>T p.K989N | Missense Mutation (SNP) | VAF 88/417 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTAN1 | c.2968A>T p.K990* | Nonsense Mutation (SNP) | VAF 85/412 reads (21%) | called by muse, mutect2, varscan2
- SV2B | c.1724T>C p.I575T | Missense Mutation (SNP) | VAF 120/494 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TEX14 | c.2507del p.P836Lfs*73 (on ENST00000240361 / NM_001201457.2; = p.P830Lfs*73 on NM_031272.5) | Frame Shift Del (DEL) | VAF 32/188 reads (17%) | called by mutect2, pindel, varscan2
- THSD7B | c.4468G>A p.G1490R (on ENST00000272643; = p.G1488R on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- VHL | c.387_390del p.V130Tfs*28 | Frame Shift Del (DEL) | VAF 93/257 reads (36%) | called by mutect2, pindel, varscan2
- ZDHHC2 | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZNF687 | c.3065T>C p.V1022A | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ACACA | c.5250C>T p.R1750= | Silent (SNP) | VAF 86/383 reads (22%) | called by muse, mutect2, varscan2
- CD4 | c.1305C>T p.I435= | Silent (SNP) | VAF 45/223 reads (20%) | catalogued as COSV50589947; called by muse, mutect2, varscan2
- CPT1A | c.189T>A p.L63= | Silent (SNP) | VAF 153/506 reads (30%) | called by muse, mutect2, varscan2
- GPLD1 | c.1062C>T p.F354= | Silent (SNP) | VAF 46/169 reads (27%) | called by muse, mutect2, varscan2
- KIF19 | c.1995C>T p.P665= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as rs1016773272, COSV63430705; called by muse, mutect2, varscan2
- KMT2B | c.4224C>A p.A1408= | Silent (SNP) | VAF 34/125 reads (27%) | called by muse, mutect2, varscan2
- MAPT | c.1791T>C p.T597= (on ENST00000262410 / NM_001377265.1; = p.T205= on NM_005910.5) | Silent (SNP) | VAF 88/341 reads (26%) | called by muse, mutect2, varscan2
- MB | c.345T>G p.V115= | Silent (SNP) | VAF 35/131 reads (27%) | called by muse, mutect2, varscan2
- NALCN | c.114T>G p.V38= | Silent (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- RHOXF2 | c.396C>T p.N132= | Silent (SNP) | VAF 140/500 reads (28%) | catalogued as rs782065383; called by muse, mutect2, varscan2
- SH3RF3 | c.2259C>T p.D753= | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as rs1322906700; called by muse, mutect2, varscan2
- SLC16A2 | c.996C>T p.A332= | Silent (SNP) | VAF 163/277 reads (59%) | catalogued as rs1232946549; called by muse, mutect2, varscan2
- SLFNL1 | c.597T>C p.S199= | Silent (SNP) | VAF 42/173 reads (24%) | called by muse, mutect2, varscan2
- SP1 | c.57A>G p.K19= (on ENST00000327443 / NM_138473.3; = p.K12= on NM_003109.1) | Silent (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- TBX6 | c.1215A>G p.V405= | Silent (SNP) | VAF 72/231 reads (31%) | called by muse, mutect2, varscan2
- TOGARAM2 | c.1386G>A p.T462= | Silent (SNP) | VAF 59/212 reads (28%) | catalogued as rs527747733, COSV65423208; called by muse, mutect2, varscan2
- UQCR10 | c.168C>T p.I56= | Silent (SNP) | VAF 88/317 reads (28%) | called by muse, mutect2, varscan2
- ZMYM2 | c.1794A>G p.T598= | Silent (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- ARRDC1 | c.1237+22G>C | Intron (SNP) | VAF 35/145 reads (24%) | called by muse, mutect2, varscan2
- BIRC8 | n.1459T>A | RNA (SNP) | VAF 46/152 reads (30%) | called by muse, mutect2, varscan2
- CD276 | c.*36G>A | 3'UTR (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- ECM2 | chr9:92536054 del TGC | 5'UTR (DEL) | VAF 23/160 reads (14%) | called by mutect2, pindel, varscan2
- EIF4E | c.*42C>A | 3'UTR (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- GP2 | chr16:20327559 T>A | 5'Flank (SNP) | VAF 82/316 reads (26%) | called by muse, mutect2, varscan2
- HNRNPH1 | c.*21T>C | Intron (SNP) | VAF 8/38 reads (21%) | catalogued as COSV61486881; called by muse, mutect2
- IFT52 | c.*19C>G | 3'UTR (SNP) | VAF 52/200 reads (26%) | called by muse, mutect2, varscan2
- KLF6 | c.*1324T>G | 3'UTR (SNP) | VAF 53/182 reads (29%) | called by muse, mutect2, varscan2
- MARK2 | c.55-6234A>G | Intron (SNP) | VAF 58/240 reads (24%) | called by muse, mutect2, varscan2
- MEIS2 | c.1147+408G>A | Intron (SNP) | VAF 74/245 reads (30%) | called by muse, mutect2, varscan2
- NCKAP1 | c.3181-34A>C | Intron (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- PDE3B | c.1029+100_1029+102del | Intron (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- REXO1L1P | n.766C>A | RNA (SNP) | VAF 119/710 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.*221C>A | 3'UTR (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- TMA16 | c.*528C>G | 3'UTR (SNP) | VAF 12/31 reads (39%) | catalogued as rs1019892970; called by muse, mutect2, varscan2
- TPM1 | c.772+68C>G | Intron (SNP) | VAF 65/303 reads (21%) | called by muse, mutect2, varscan2
- VASP | c.873+16T>A | Intron (SNP) | VAF 73/252 reads (29%) | called by muse, mutect2, varscan2
